Surgical pathology report (de-identified scan), TCGA case TCGA-AG-A01L, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-A01L-01A (Primary Tumor).

Sample ID #:

Diagnosis:

Resected colon (rectosigmoid) with a rectal carcinoma characterized histologically as a moderately differentiated colorectal adenocarcinoma, extending up to 0.5 cm to the aboral resection margin. Invasive spread of the tumor on all intestinal wall layers, as far as the adjacent periproctal soft tissue. Carcinomatous lymphangiosis processes in the region of the tumor margin. Distance of the tumor to the resection margin of the periproctial soft tissue measures 0.5 cm.

Oral and aboral resection margin, resection margin of the periproctial soft tissue and isolated colon sections are all tumor-free.

Two of 47 lymph nodes with metastases of the rectal carcinoma, partly transgressing the lymph node capsules. Remaining lymph nodes with uncharacteristically reactive changes.

Stage of tumor: pT3, pN1, L1, V0; G2 R0.

ICD-O-3

adenocarcinoma, NOS 8140/3

Site: Rectum C20.9 p 3/31/11

HIP/AA Discrepancy		
Case is (title):		
Reviewed: 5/10/11		

Source: NCI Genomic Data Commons file 6190c83e-ba9c-4152-8554-e8b723e6ebf8 (TCGA-AG-A01L.50C35570-402A-419C-8060-C026A947988B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).